Somatic mutation profile of tumor specimen TCGA-50-6597-01A (aliquot TCGA-50-6597-01A-11D-1855-08) from TCGA case TCGA-50-6597, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.9 years (29,195 days).
Specimen TCGA-50-6597-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1957b5d-d45b-4556-9352-3af184e725f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-6597-10A (Blood Derived Normal), aliquot TCGA-50-6597-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4d95448-280a-432c-adc2-c04dfd8944a2

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, Nonsense Mutation 4, Splice Site 4, Intron 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP2 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV57040833; called by muse, mutect2, varscan2
- ADCY3 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1230988837, COSV53172867; called by muse, mutect2, varscan2
- ARHGAP39 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772777813, COSV52775951; called by muse, mutect2, varscan2
- BPIFB1 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53608887; called by muse, mutect2, varscan2
- BTN2A1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV57005146; called by muse, mutect2, varscan2
- CEBPZ | c.929G>C p.R310P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV50018623; called by muse, mutect2, varscan2
- CLTC | c.4631C>G p.S1544C | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52253173; called by muse, mutect2
- DAW1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59369257; called by muse, mutect2, varscan2
- DNAH8 | c.6632G>A p.W2211* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as COSV59481013; called by muse, mutect2, varscan2
- DPY19L2 | c.2057G>T p.R686I | Missense Mutation (SNP) | VAF 36/433 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100194182; called by muse, mutect2
- EIF2S3 | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 67/1618 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53408239; called by muse, mutect2
- EPB41L1 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs201212477; called by muse, mutect2, varscan2
- FAM90A1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as rs777353446, COSV56714868; called by muse, mutect2, varscan2
- GMEB2 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56609744; called by muse, mutect2, varscan2
- GNL1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV64835561; called by muse, varscan2
- GNL1 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV64835564; called by muse, varscan2
- HLA-A | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as rs41541518, CM004196; called by muse, mutect2, varscan2
- HMCN1 | c.9409G>T p.G3137* | Nonsense Mutation (SNP) | VAF 7/106 reads (7%) | catalogued as COSV54942314; called by muse, mutect2
- KCNJ15 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs772307086, COSV60812014; called by muse, mutect2, varscan2
- LRP1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as rs768155333, COSV54526100; called by muse, mutect2
- OR51A7 | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100834734, COSV63788974; called by muse, mutect2, varscan2
- PCARE | c.358G>C p.G120R | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs140625913, COSV59058249; called by muse, mutect2, varscan2
- PPFIA1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 110/389 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV54140876; called by muse, mutect2, varscan2
- RANBP17 | c.1981T>G p.F661V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV66657245; called by muse, varscan2
- SPTA1 | c.2571C>A p.N857K | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs754041614, COSV63759634; called by muse, mutect2, varscan2
- STAC | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs369536237; called by muse, mutect2, varscan2
- TPR | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV66605117; called by muse, mutect2, varscan2
- TTC13 | c.1301-1G>A p.X434_splice | Splice Site (SNP) | VAF 29/79 reads (37%) | catalogued as COSV64170109; called by muse, mutect2, varscan2
- USH2A | c.10106A>T p.K3369I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV56438337; called by muse, mutect2
- WNT16 | c.96-1G>A p.X32_splice (on ENST00000222462 / NM_057168.2; = p.X22_splice on NM_016087.2) | Splice Site (SNP) | VAF 15/116 reads (13%) | catalogued as COSV99743295; called by muse, mutect2, varscan2
- ZNF483 | c.413-1G>A p.X138_splice | Splice Site (SNP) | VAF 16/108 reads (15%) | catalogued as COSV58515804, COSV58517306; called by muse, mutect2, varscan2
- CUL4B | c.640_662del p.D214Rfs*9 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- GPR174 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MET | c.3027_3028+3delinsC p.X1009_splice | Splice Site (DEL) | VAF 17/49 reads (35%) | called by pindel, varscan2*
- NXPE1 | c.1143C>G p.I381M (on ENST00000424269; = p.I239M on NM_152315.5) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PNMA5 | c.543_556delinsCGG p.Q181Hfs*9 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | called by pindel, varscan2*
- PRDM7 | c.632T>C p.F211S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TFCP2 | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- FNDC11 | c.690C>T p.V230= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs1232046082; called by muse, mutect2, varscan2
- HAO1 | c.921C>T p.G307= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs748303742, COSV66493781; called by muse, mutect2, varscan2
- KCNJ4 | c.96C>T p.F32= | Silent (SNP) | VAF 66/300 reads (22%) | catalogued as rs868750773, COSV57858845; called by muse, mutect2, varscan2
- KEL | c.1743C>T p.H581= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs377071873; called by muse, mutect2, varscan2
- LRRC74A | c.1164G>A p.P388= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs754699247, COSV53610752; called by muse, mutect2, varscan2
- PLXNA3 | c.5007G>C p.V1669= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV63755734; called by muse, mutect2, varscan2
- PMP22 | c.219C>T p.I73= | Silent (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- SF1 | c.1653C>G p.A551= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV57117490; called by muse, mutect2, varscan2
- SLC46A2 | c.1002C>T p.S334= | Silent (SNP) | VAF 45/64 reads (70%) | catalogued as COSV65289974; called by muse, mutect2, varscan2
- SMAD9 | c.1245G>A p.R415= (on ENST00000379826 / NM_001127217.3; = p.R378= on NM_005905.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV63206387; called by muse, mutect2, varscan2
- TENT5B | c.946C>T p.L316= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV56694041; called by muse, mutect2
- TRIL | c.1338C>T p.L446= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs370254572, COSV59868072; called by mutect2, varscan2
- TRIML2 | c.1044C>T p.T348= | Silent (SNP) | VAF 37/221 reads (17%) | catalogued as rs371374323; called by muse, mutect2, varscan2
- USH2A | c.10104G>A p.Q3368= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV56339233; called by muse, mutect2
- VIL1 | c.1869G>A p.E623= | Silent (SNP) | VAF 94/258 reads (36%) | catalogued as COSV50298009; called by muse, varscan2
- XRN1 | c.1485C>T p.I495= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV53818241; called by muse, mutect2, varscan2
- JAK1 | c.-162+8184G>A | Intron (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- PLCB1 | c.3423+11883T>C | Intron (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- TUBB7P | n.801G>A | RNA (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
